Somatic mutation profile of tumor specimen CDDP-ACM9-TTP1-A (aliquot CDDP-ACM9-TTP1-A-2-0-D-A572-36) from CDDP_EAGLE case CDDP-ACM9, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 75 years.
Specimen CDDP-ACM9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a72b3ed-ccc1-4644-b64a-bec0a26681c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACM9-NB1-A (Blood Derived Normal), aliquot CDDP-ACM9-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c59ca54e-261a-4d43-90df-a38af33b74f6

The open-access MAF lists 1,009 somatic variants for this specimen: 677 protein-altering or splice-affecting, 198 silent, 134 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 566, Silent 198, Intron 60, Nonsense Mutation 50, RNA 27, Frame Shift Del 21, Splice Site 16, 5'UTR 15, 3'UTR 14, Frame Shift Ins 12, 5'Flank 11, Splice Region 7.

Variants (750 of 1,009; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 24/170 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706780, COSV66707774; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 93/253 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD16B | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1302408728; called by muse, mutect2, varscan2
- ADA | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 148/507 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.106); catalogued as rs756480576; called by muse, mutect2, varscan2
- ADAM19 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as COSV57435727; called by muse, mutect2, varscan2
- ADAMDEC1 | c.988C>G p.P330A | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); catalogued as rs781324239; called by muse, mutect2, varscan2
- ADAMTS12 | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs757718642; called by muse, mutect2, varscan2
- ADAMTS16 | c.3053C>T p.P1018L | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.918); catalogued as rs774065197; called by muse, mutect2, varscan2
- ADAMTS18 | c.1603G>C p.G535R | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as rs755079078, COSV99273312; called by muse, mutect2, varscan2
- ADAMTS18 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as rs538039525; called by muse, mutect2, varscan2
- AGAP3 | c.1096G>T p.A366S (on ENST00000622464; = p.A402S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.514); catalogued as rs1467522036; called by muse, mutect2, varscan2
- AGTR2 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 94/168 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100903535; called by muse, mutect2, varscan2
- AKAP6 | c.6482A>T p.E2161V | Missense Mutation (SNP) | VAF 62/359 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); catalogued as rs1339270972; called by muse, mutect2, varscan2
- ANK2 | c.3373G>T p.D1125Y | Missense Mutation (SNP) | VAF 123/306 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52152098; called by muse, mutect2, varscan2
- APC | c.4729G>T p.E1577* | Nonsense Mutation (SNP) | VAF 57/368 reads (15%) | catalogued as CM086525, COSV57322139, COSV99072962; called by muse, mutect2, varscan2
- ARSI | c.1472G>T p.R491L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV60816809; called by muse, mutect2, varscan2
- ASTN2 | c.1743G>C p.K581N (on ENST00000313400 / NM_001365069.1; = p.K530N on NM_014010.5) | Missense Mutation (SNP) | VAF 112/190 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); catalogued as COSV57760866; called by muse, mutect2, varscan2
- AUTS2 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 45/376 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as rs772352925, COSV61423391; called by muse, mutect2, varscan2
- AXDND1 | c.2860C>A p.H954N | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.666); catalogued as COSV62642973; called by muse, mutect2, varscan2
- BAAT | c.680C>G p.S227* | Nonsense Mutation (SNP) | VAF 92/206 reads (45%) | catalogued as rs776895987; called by muse, mutect2, varscan2
- BDKRB1 | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756127924; called by muse, mutect2, varscan2
- BID | c.388C>T p.R130W (on ENST00000317361 / NM_197966.2; = p.R84W on NM_001196.4) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs148107209; called by muse, mutect2, varscan2
- BRINP2 | c.1904G>T p.W635L | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV100838416; called by muse, mutect2, varscan2
- BRINP3 | c.1343C>A p.A448D | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.42); catalogued as COSV100818396; called by muse, mutect2, varscan2
- BTNL9 | c.887-2A>G p.X296_splice | Splice Site (SNP) | VAF 20/150 reads (13%) | catalogued as rs1259362907, COSV100576076, COSV59796285; called by muse, mutect2, varscan2
- C20orf85 | c.294C>A p.F98L | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV64519585; called by muse, mutect2, varscan2
- C5AR2 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs200440279; called by muse, mutect2, varscan2
- CACHD1 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs764742615, COSV51554072; called by muse, mutect2, varscan2
- CACNA1A | c.1628C>A p.T543K | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV64196090; called by muse, mutect2, varscan2
- CAPNS2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs754652916, COSV50900036; called by muse, mutect2, varscan2
- CASZ1 | c.3715C>T p.R1239C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1327273694, COSV59737807; called by muse, mutect2, varscan2
- CC2D2A | c.245G>A p.R82Q (on ENST00000424120 / NM_001378615.1; = p.T117= on NM_020785.2) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs527974001; called by muse, mutect2, varscan2
- CCDC158 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 129/286 reads (45%) | catalogued as COSV101187265; called by muse, mutect2, varscan2
- CCDC89 | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs1460901707; called by muse, mutect2, varscan2
- CDH10 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 44/588 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs376632889; called by muse, mutect2
- CDH18 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV56941244; called by muse, mutect2, varscan2
- CDH18 | c.102G>T p.M34I | Missense Mutation (SNP) | VAF 110/522 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56915457, COSV99935876; called by mutect2, varscan2
- CDH9 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 61/298 reads (20%) | catalogued as rs1345943568; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 235/472 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62577501; called by muse, mutect2, varscan2
- CHRNE | c.1054C>A p.R352S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1384258026; called by muse, mutect2, varscan2
- CNTN6 | c.2513A>G p.Y838C | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374372478; called by muse, mutect2, varscan2
- COL19A1 | c.3057G>T p.K1019N | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs771562232, COSV59591570; called by muse, mutect2, varscan2
- COL1A2 | c.1612G>A p.G538S | Missense Mutation (SNP) | VAF 164/610 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51967501; called by muse, mutect2, varscan2
- COL21A1 | c.2137G>T p.G713* | Nonsense Mutation (SNP) | VAF 30/216 reads (14%) | catalogued as COSV99777519; called by muse, mutect2, varscan2
- COL5A2 | c.2374G>T p.G792* | Nonsense Mutation (SNP) | VAF 66/471 reads (14%) | catalogued as COSV66407805; called by muse, mutect2, varscan2
- CPNE8 | c.311G>C p.S104T | Missense Mutation (SNP) | VAF 84/344 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.1); catalogued as rs778884699; called by muse, mutect2, varscan2
- CPS1 | c.2519G>T p.R840I | Missense Mutation (SNP) | VAF 88/448 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV51805823; called by muse, mutect2, varscan2
- CRAMP1 | c.2670G>T p.Q890H | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51965014; called by muse, mutect2, varscan2
- CRNN | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 38/720 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1358346844, COSV55122707; called by muse, mutect2
- CSHL1 | c.203C>A p.T68K | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs770526316, COSV51990426; called by muse, mutect2, varscan2
- CYP11B1 | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 117/358 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as CM1511260, COSV99454582; called by muse, mutect2, varscan2
- DCDC2 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1471197198; called by muse, mutect2, varscan2
- DEFA5 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs758909444, COSV100400502; called by muse, mutect2, varscan2
- DLGAP3 | c.233C>A p.A78E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.035); catalogued as COSV52391240; called by mutect2, varscan2
- DMWD | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 34/225 reads (15%) | catalogued as COSV99353615; called by muse, mutect2, varscan2
- DNAH7 | c.5713G>T p.V1905F | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV56775635; called by muse, mutect2, varscan2
- DNAH7 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as COSV56782722; called by muse, mutect2, varscan2
- DNAH9 | c.12010C>T p.P4004S | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52378023; called by muse, mutect2, varscan2
- EGLN3 | c.588C>A p.H196Q | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51655945; called by muse, mutect2, varscan2
- EPHA5 | c.1463C>G p.S488C | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99896920; called by muse, mutect2, varscan2
- EPHA6 | c.2658G>A p.M886I (on ENST00000389672 / NM_001080448.3; = p.M278I on NM_173655.4) | Missense Mutation (SNP) | VAF 55/436 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV67556533, COSV67597800; called by muse, mutect2, varscan2
- EYA4 | c.242G>T p.W81L | Missense Mutation (SNP) | VAF 116/315 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV62057395; called by muse, mutect2, varscan2
- FAM13B | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs763768037; called by muse, mutect2, varscan2
- FAT3 | c.9193C>T p.R3065* | Nonsense Mutation (SNP) | VAF 52/110 reads (47%) | catalogued as COSV53082790; called by muse, mutect2, varscan2
- FGF10 | c.5G>T p.W2L | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as COSV52936591; called by muse, mutect2, varscan2
- FLG | c.7039G>T p.G2347W | Missense Mutation (SNP) | VAF 380/997 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs902235973; called by muse, mutect2, varscan2
- FLG | c.58A>G p.K20E | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs751162672; called by muse, mutect2, varscan2
- FOXP2 | c.2066T>A p.L689* | Nonsense Mutation (SNP) | VAF 60/192 reads (31%) | catalogued as COSV63487044; called by muse, mutect2, varscan2
- FREM3 | c.4397G>T p.R1466L | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV61679493; called by muse, mutect2, varscan2
- FSIP2 | c.20036G>A p.G6679D | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs767798092; called by muse, mutect2, varscan2
- FSTL5 | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.817); catalogued as COSV60186689; called by muse, mutect2, varscan2
- GABRA2 | c.702A>T p.T234= | Splice Region (SNP) | VAF 27/75 reads (36%) | catalogued as COSV62920733; called by muse, varscan2
- GABRB3 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV54687737; called by muse, mutect2, varscan2
- GCNT4 | c.1298G>C p.R433T | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV100466422; called by muse, mutect2, varscan2
- GHSR | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV53840407, COSV53840935; called by muse, mutect2, varscan2
- GNAZ | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV50736897; called by muse, mutect2, varscan2
- GOLGB1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 34/522 reads (7%) | catalogued as COSV61463311; called by muse, mutect2
- GPAT3 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV52355683; called by muse, mutect2, varscan2
- GPLD1 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs367805287; called by muse, mutect2, varscan2
- GPSM1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1244767732, COSV61305327; called by muse, mutect2, varscan2
- GRK4 | c.1319C>T p.A440V (on ENST00000398052 / NM_182982.3; = p.A408V on NM_005307.3) | Missense Mutation (SNP) | VAF 102/221 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.2); catalogued as rs747003103, COSV61667925; called by muse, mutect2, varscan2
- H2BC10 | c.122A>T p.Y41F | Missense Mutation (SNP) | VAF 94/395 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV59953127; called by muse, mutect2, varscan2
- HMCN1 | c.15380C>T p.T5127I | Missense Mutation (SNP) | VAF 124/343 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs375549812; called by muse, mutect2, varscan2
- HNRNPAB | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs377150533; called by muse, mutect2, varscan2
- HS1BP3 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs765692930; called by muse, mutect2
- HTR4 | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 57/167 reads (34%) | catalogued as COSV58796120; called by muse, mutect2, varscan2
- IGSF1 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 81/142 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV100811807, COSV63837060; called by muse, mutect2, varscan2
- IL2RG | c.722G>A p.S241N | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CD991765, CM940979; called by muse, mutect2, varscan2
- IPO13 | c.2028C>T p.P676= | Splice Region (SNP) | VAF 28/70 reads (40%) | catalogued as rs146256412; called by muse, mutect2, varscan2
- KCNK10 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 160/527 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.15); catalogued as rs781600628, COSV56648735; called by muse, mutect2, varscan2
- KCNT1 | c.483G>T p.Q161H (on ENST00000488444; = p.Q180H on NM_020822.3) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53711975; called by muse, mutect2, varscan2
- KDM6A | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100937908, COSV65038917; called by muse, mutect2, varscan2
- KHNYN | c.432G>T p.W144C | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs746617915; called by muse, mutect2, varscan2
- KIF21B | c.1804G>T p.E602* | Nonsense Mutation (SNP) | VAF 15/146 reads (10%) | catalogued as COSV59764260; called by muse, mutect2
- KLHL6 | c.1023C>A p.D341E | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV100384304; called by muse, mutect2, varscan2
- KRTAP10-7 | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59113966; called by muse, mutect2, varscan2
- KRTAP4-5 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.282); catalogued as COSV100576842, COSV58351676; called by muse, mutect2, varscan2
- LRCH2 | c.2199T>A p.H733Q | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.683); catalogued as rs1556523252; called by muse, varscan2
- LRRIQ3 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63041472, COSV63043737; called by muse, mutect2, varscan2
- LUZP2 | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs752904146; called by muse, mutect2, varscan2
- MAPK3 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53771070; called by muse, mutect2, varscan2
- MEP1B | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1288958310, COSV99329057; called by muse, mutect2, varscan2
- MGAM | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.592); catalogued as COSV71886272; called by muse, mutect2, varscan2
- MGAM2 | c.3820C>A p.P1274T | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332099181; called by muse, mutect2, varscan2
- MME | c.1500G>T p.L500F | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs767285200; called by mutect2, varscan2
- MUC12 | c.14777C>A p.A4926D (on ENST00000379442; = p.A4783D on NM_001164462.1) | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT tolerated (0.52); catalogued as rs756234412; called by muse, mutect2, varscan2
- MUC16 | c.14032A>T p.M4678L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs767738671, COSV67447922; called by muse, mutect2, varscan2
- MUC17 | c.96C>A p.N32K | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV100075295; called by muse, mutect2, varscan2
- MUC5AC | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT deleterious (0); catalogued as COSV100650564; called by muse, mutect2, varscan2
- MX1 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as rs141166870, COSV55819617; called by muse, mutect2, varscan2
- MYH1 | c.2962G>A p.G988S | Missense Mutation (SNP) | VAF 58/403 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1286207500, COSV56848217; called by muse, mutect2, varscan2
- MYO15B | c.2416G>T p.D806Y | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs1394015332; called by muse, mutect2, varscan2
- MYO18B | c.3004C>T p.L1002F | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.968); catalogued as rs1195369011, COSV59126740, COSV59129438; called by muse, mutect2, varscan2
- MYT1 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs758902158; called by muse, mutect2
- NAV3 | c.337del p.L113* | Frame Shift Del (DEL) | VAF 59/277 reads (21%) | catalogued as COSV57070379; called by mutect2, pindel, varscan2
- NAV3 | c.4334G>A p.R1445H | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs768831417, COSV99893890; called by muse, mutect2
- NBPF20 | c.4355C>T p.A1452V (on ENST00000369373; = p.A1107V on NM_001278267.1) | Missense Mutation (SNP) | VAF 271/929 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs1218643304; called by muse, mutect2, varscan2
- NCAM2 | c.194A>T p.Q65L | Missense Mutation (SNP) | VAF 98/327 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV53082585; called by muse, mutect2, varscan2
- NCAM2 | c.1133A>T p.Y378F | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.143); catalogued as COSV53089164; called by muse, mutect2, varscan2
- NLGN1 | c.1198G>T p.V400L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV64329009; called by muse, varscan2
- NPR1 | c.2221G>T p.V741L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV64117472; called by muse, mutect2, varscan2
- NRG1 | c.836G>T p.R279L (on ENST00000405005 / NM_013964.5; = p.R284L on NM_013956.5) | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV55180241; called by muse, mutect2, varscan2
- OCA2 | c.1053C>A p.H351Q | Missense Mutation (SNP) | VAF 79/312 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD982838; called by muse, mutect2, varscan2
- OR10G8 | c.338T>A p.L113H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101461885; called by muse, mutect2, varscan2
- OR10K2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59221468; called by muse, mutect2
- OR14A16 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as COSV100713812, COSV62926244; called by muse, mutect2, varscan2
- OR2D2 | c.575C>A p.T192N | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs759940797; called by muse, mutect2, varscan2
- OR2L8 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1194452473; called by muse, mutect2, varscan2
- OR2M2 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV62898758; called by muse, mutect2, varscan2
- OR2T10 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1239570146; called by muse, mutect2, varscan2
- OR51Q1 | c.208C>A p.L70M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV56180141; called by muse, mutect2, varscan2
- OR52L1 | c.920C>G p.P307R | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59985955; called by muse, mutect2, varscan2
- OR5D13 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV100686764; called by muse, mutect2, varscan2
- OR5L2 | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV65723794; called by muse, mutect2, varscan2
- OR6A2 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60264794; called by muse, mutect2, varscan2
- OTOGL | c.1483G>C p.D495H (on ENST00000547103; = p.D486H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101508997; called by muse, mutect2, varscan2
- OVCH1 | c.1973C>G p.T658R | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100548233; called by muse, mutect2, varscan2
- PBXIP1 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs757059898; called by muse, mutect2
- PCDH19 | c.2525A>T p.N842I (on ENST00000373034 / NM_001184880.2; = p.N795I on NM_020766.3) | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.771); catalogued as COSV55267010; called by muse, mutect2, varscan2
- PCDHA13 | c.2237G>A p.G746E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.589); catalogued as COSV56475728; called by muse, mutect2, varscan2
- PCDHB3 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.033); catalogued as COSV50573260; called by muse, mutect2, varscan2
- PCDHGB1 | c.566C>A p.P189Q | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53896817, COSV53968962; called by muse, mutect2, varscan2
- PCDHGB4 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452714844; called by muse, varscan2
- PDGFRA | c.548C>A p.T183N | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57277204; called by muse, mutect2, varscan2
- PDZD3 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs201135995; called by muse, mutect2, varscan2
- PKD1 | c.5866G>T p.V1956L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs781454286; called by mutect2, varscan2
- PLCL1 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV70859911; called by muse, mutect2, varscan2
- PLEC | c.13670G>A p.R4557H (on ENST00000322810 / NM_201380.4; = p.R4447H on NM_000445.5) | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs782580027, COSV59662014; called by muse, mutect2
- PLPPR5 | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54175378; called by muse, mutect2, varscan2
- PML | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51443684; called by muse, mutect2, varscan2
- PPARGC1B | c.2282G>T p.R761L | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs755486310, COSV58530310; called by muse, mutect2, varscan2
- PPP2R5C | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV58271757; called by muse, mutect2, varscan2
- PTPRD | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100643398; called by muse, mutect2, varscan2
- PTPRH | c.2168C>A p.P723Q | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770794405, COSV54748172; called by muse, mutect2, varscan2
- PTPRH | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 89/389 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs200319382, COSV54748346; called by muse, mutect2, varscan2
- PTPRJ | c.1000G>T p.G334W | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69252723, COSV69254236; called by muse, mutect2, varscan2
- RAD50 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs758063640; called by muse, mutect2, varscan2
- RBMXL3 | c.2776G>A p.G926R | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs781783386, COSV100407147; called by muse, mutect2, varscan2
- RELN | c.8423C>A p.S2808Y | Missense Mutation (SNP) | VAF 157/512 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV100634040; called by muse, mutect2, varscan2
- RFXANK | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 68/331 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs368808881; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGPD1 | c.1270G>T p.G424C (on ENST00000409776; = p.G432C on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/856 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs769917892, COSV101233716; called by muse, mutect2, varscan2
- RGSL1 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1252770946; called by muse, mutect2
- RRM1 | c.450G>C p.T150= | Splice Region (SNP) | VAF 46/142 reads (32%) | catalogued as COSV56166656; called by muse, mutect2, varscan2
- RTL1 | c.1427C>A p.T476K | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101128249, COSV66017246; called by muse, mutect2, varscan2
- RYR2 | c.14497G>C p.D4833H | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1277507848, COSV63686058, COSV63688563; called by muse, mutect2, varscan2
- SCN1A | c.5869G>T p.E1957* (on ENST00000303395 / NM_001202435.3; = p.E1946* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 52/175 reads (30%) | catalogued as rs1553519769, COSV57658619; called by muse, mutect2, varscan2
- SCN4A | c.1272G>C p.M424I | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.149); catalogued as COSV101438303; called by muse, mutect2, varscan2
- SCN9A | c.3413_3415del p.G1138del (on ENST00000303354; = p.G1127del on NM_002977.3) | In Frame Del (DEL) | VAF 35/356 reads (10%) | catalogued as rs1418929911; called by mutect2, pindel, varscan2
- SERPINA12 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs545704158; called by muse, mutect2, varscan2
- SIGLEC6 | c.113C>A p.S38* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV58432523; called by muse, mutect2, varscan2
- SIGLECL1 | c.170T>A p.V57E | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1297453102; called by muse, mutect2, varscan2
- SLC23A3 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.138); catalogued as COSV99841115; called by muse, varscan2
- SLC2A13 | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as rs745992233; called by muse, mutect2, varscan2
- SLC33A1 | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100848265; called by muse, mutect2, varscan2
- SLC5A11 | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 125/385 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV100762637; called by muse, mutect2, varscan2
- SMYD1 | c.782A>G p.E261G | Missense Mutation (SNP) | VAF 66/304 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs996898301; called by muse, mutect2
- SMYD1 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1265884967; called by muse, mutect2
- SP4 | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as rs765285909; called by muse, mutect2, varscan2
- SPTA1 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 169/473 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as COSV63754563; called by muse, mutect2, varscan2
- SRCAP | c.2191G>C p.D731H | Missense Mutation (SNP) | VAF 83/296 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52670805; called by muse, mutect2, varscan2
- STPG2 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as COSV99757608; called by muse, mutect2
- TAS2R42 | c.536_537del p.S179Yfs*33 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs747949093; called by pindel, varscan2
- TENT5D | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57637485; called by muse, mutect2, varscan2
- THBS2 | c.1871C>G p.P624R | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as rs1327983689; called by muse, mutect2, varscan2
- THOP1 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs150927880; called by mutect2, varscan2
- THSD7B | c.620T>A p.I207K | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99758960; called by muse, mutect2, varscan2
- TMED3 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs951475757; called by muse, mutect2, varscan2
- TMEM196 | c.204+1G>C p.X68_splice | Splice Site (SNP) | VAF 50/207 reads (24%) | catalogued as COSV68254076; called by muse, mutect2, varscan2
- TMEM196 | c.204C>T p.V68= | Splice Region (SNP) | VAF 51/212 reads (24%) | catalogued as rs1409261050; called by muse, mutect2, varscan2
- TMEM40 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs201284335, COSV53145311; called by muse, mutect2, varscan2
- TOX2 | c.148G>T p.V50L (on ENST00000358131 / NM_001098798.2; = p.V41L on NM_001098797.2) | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as rs144756563, COSV100364447; called by muse, varscan2
- TRAV37 | n.52+1G>A | Splice Site (SNP) | VAF 34/138 reads (25%) | catalogued as rs890183645; called by muse, mutect2, varscan2
- TRIM10 | c.306C>A p.H102Q | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780131047; called by muse, varscan2
- TRIM55 | c.1015G>T p.G339* | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as COSV52545633; called by muse, mutect2, varscan2
- TRPV1 | c.1672G>A p.G558S | Missense Mutation (SNP) | VAF 91/187 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1391024854, COSV99439425; called by muse, mutect2, varscan2
- TTBK2 | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 56/323 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51157810; called by muse, mutect2, varscan2
- USH2A | c.5992C>A p.R1998S | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV100233651, COSV56366217; called by muse, mutect2, varscan2
- VSTM2B | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 114/180 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV59258853; called by muse, mutect2, varscan2
- WFDC10B | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57913127; called by muse, mutect2, varscan2
- ZDHHC11 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs768620537; called by muse, mutect2, varscan2
- ZFHX4 | c.3932C>A p.A1311D | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV51491020; called by muse, mutect2, varscan2
- ZIM3 | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54146954; called by muse, mutect2, varscan2
- ZNF208 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV68105920; called by muse, mutect2, varscan2
- ZNF223 | c.1298G>T p.C433F | Missense Mutation (SNP) | VAF 113/238 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71572204; called by muse, mutect2, varscan2
- ZNF28 | c.504C>G p.I168M | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1568647245, COSV60423652; called by muse, mutect2, varscan2
- ZNF469 | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 64/326 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.245); catalogued as COSV99081581; called by muse, varscan2
- ZNF470 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV57967714, COSV57970751; called by mutect2, varscan2
- ZNF536 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 102/168 reads (61%) | catalogued as COSV62821898, COSV62827945; called by muse, mutect2, varscan2
- ZNF567 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 106/180 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1568707356; called by muse, mutect2, varscan2
- ZNF626 | c.90G>C p.R30S | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99391640; called by muse, mutect2, varscan2
- ZNF780B | c.95G>T p.R32M | Missense Mutation (SNP) | VAF 302/592 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV55468783; called by muse, mutect2, varscan2
- ZNF853 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV71922779; called by muse, mutect2, varscan2
- ABCB1 | c.3192G>T p.Q1064H | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ABCC11 | c.982C>G p.Q328E | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ABHD4 | c.60G>T p.W20C | Missense Mutation (SNP) | VAF 144/428 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABRAXAS2 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 90/160 reads (56%) | called by muse, mutect2, varscan2
- ACACA | c.5489G>T p.G1830V | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACADM | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 87/266 reads (33%) | called by muse, mutect2, varscan2
- ACSM2B | c.1357G>T p.D453Y | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ACSM2B | c.83G>C p.R28T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by mutect2, varscan2
- ADAM30 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ADAMTS5 | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADCY1 | c.2969dup p.A991Rfs*21 | Frame Shift Ins (INS) | VAF 42/204 reads (21%) | called by mutect2, pindel, varscan2
- ADCY2 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 22/354 reads (6%) | called by muse, mutect2
- ADD2 | c.705+1G>T p.X235_splice | Splice Site (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- ADGB | c.2078G>C p.R693P | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ADGRL3 | c.4217G>T p.S1406I (on ENST00000506720 / NM_001322402.2; = p.S1295I on NM_015236.6) | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADNP2 | c.698A>G p.H233R | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFDN | c.5374A>C p.K1792Q (on ENST00000447894 / NM_001366320.1; = p.K1711Q on NM_001207008.1) | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- AGBL1 | c.369G>T p.W123C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AGBL3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- AIPL1 | c.817G>C p.A273P | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP11 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 96/178 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKR1C8P | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- AL035078.4 | c.101G>C p.R34T | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- AL138999.2 | n.839-3T>C | Splice Region (SNP) | VAF 19/234 reads (8%) | called by muse, mutect2, varscan2
- ANK2 | c.3372G>T p.M1124I | Missense Mutation (SNP) | VAF 126/308 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- ANOS1 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 63/143 reads (44%) | called by muse, mutect2, varscan2
- ANXA2R | c.175A>T p.S59C | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- APOA5 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- APOB | c.3550G>C p.V1184L | Missense Mutation (SNP) | VAF 51/359 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- APOBR | c.2806G>T p.G936C (on ENST00000431282; = p.G945C on NM_018690.4) | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- ARHGAP11A | c.2051G>T p.R684I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ARHGAP32 | c.1830G>T p.Q610H (on ENST00000310343 / NM_001378025.1; = p.Q261H on NM_014715.4) | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ARL5A | c.516G>T p.M172I | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2
- ARMH1 | c.980G>T p.R327L | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARSH | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASXL3 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP1A3 | c.1883A>T p.K628M (on ENST00000545399 / NM_001256214.2; = p.K615M on NM_152296.5) | Missense Mutation (SNP) | VAF 189/431 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- ATP1A4 | c.1855G>C p.V619L | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, varscan2
- BAZ2B | c.4139A>T p.D1380V | Missense Mutation (SNP) | VAF 77/400 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BIRC6 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 82/308 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- BRD1 | c.1902_1905dup p.D636Yfs*3 | Frame Shift Ins (INS) | VAF 24/160 reads (15%) | called by mutect2, pindel, varscan2
- BRIP1 | c.3205C>A p.Q1069K | Missense Mutation (SNP) | VAF 43/634 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.492); called by muse, mutect2
- BRWD3 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 96/169 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C11orf86 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- C16orf90 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- C16orf96 | c.1742C>A p.A581D | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- C1QTNF1 | c.705C>A p.S235R | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C2CD4D | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 171/291 reads (59%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C6orf118 | c.280G>T p.V94L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CACNA1E | c.1571C>A p.S524Y | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CACNA1E | c.4620C>A p.D1540E | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- CALN1 | c.217A>T p.S73C (on ENST00000329008 / NM_001017440.3; = p.S115C on NM_031468.4) | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CAMK2A | c.1337C>A p.T446N (on ENST00000348628 / NM_171825.2; = p.T457N on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPS2 | c.1269T>G p.N423K | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2
- CBLB | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 85/254 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC141 | c.1126C>G p.L376V | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CCDC150 | c.1508A>T p.K503M | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.11800A>G p.K3934E | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CCDC178 | c.1932+1G>T p.X644_splice | Splice Site (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2
- CCDC180 | c.2593G>T p.D865Y | Missense Mutation (SNP) | VAF 133/289 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CCNO | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CD274 | c.718C>G p.H240D | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CD33 | c.1090del p.Q364Sfs*38 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- CDH17 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); called by muse, mutect2
- CDH23 | c.6142C>A p.L2048M | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CDH8 | c.1498T>G p.Y500D | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CDH8 | c.1253C>A p.P418H | Missense Mutation (SNP) | VAF 111/497 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDO1 | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- CELA3A | c.469T>A p.C157S | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP85 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CETN2 | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 84/155 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP44 | c.3671A>T p.K1224I | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CFAP44 | c.3492C>G p.I1164M | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CFH | c.1504C>G p.Q502E | Missense Mutation (SNP) | VAF 128/393 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- CLASP1 | c.152T>A p.V51E | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLCN5 | c.1897G>T p.G633C | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLIP4 | c.1134C>A p.D378E | Missense Mutation (SNP) | VAF 50/391 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CNTFR | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, varscan2
- COG4 | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- COL27A1 | c.3835G>T p.G1279C | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL2A1 | c.1266+2T>A p.X422_splice | Splice Site (SNP) | VAF 362/1081 reads (33%) | called by muse, mutect2, varscan2
- COL5A3 | c.3404A>G p.D1135G | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- COL9A3 | c.836A>T p.K279M | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- COL9A3 | c.903C>A p.G301= | Splice Region (SNP) | VAF 159/411 reads (39%) | called by muse, mutect2, varscan2
- COX6A2 | c.211-2A>T p.X71_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- CPXM1 | c.1991T>A p.L664Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CR1 | c.5920A>T p.I1974L | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.175); called by muse, mutect2
- CRIP2 | c.346G>C p.V116L | Missense Mutation (SNP) | VAF 84/269 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CRISPLD1 | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYBG2 | c.3045dup p.V1016Rfs*28 | Frame Shift Ins (INS) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- CSMD3 | c.8378G>T p.G2793V (on ENST00000297405 / NM_001363185.1; = p.G2624V on NM_052900.3) | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.2741A>T p.Y914F (on ENST00000297405 / NM_001363185.1; = p.Y810F on NM_052900.3) | Missense Mutation (SNP) | VAF 55/348 reads (16%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSRNP3 | c.1690C>A p.L564I | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.953); called by muse, mutect2
- CWC27 | c.86G>T p.W29L | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CX3CL1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CYP4F3 | c.1174C>T p.H392Y | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DCAF12L1 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DCAF16 | c.27_56del p.D9_E18del | In Frame Del (DEL) | VAF 16/94 reads (17%) | called by mutect2, pindel
- DCHS1 | c.4667A>T p.E1556V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- DENND4C | c.3931G>T p.E1311* (on ENST00000434457 / NM_001330640.2; = p.E1262* on NM_017925.7) | Nonsense Mutation (SNP) | VAF 70/230 reads (30%) | called by muse, mutect2, varscan2
- DHX36 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- DLGAP4 | c.2679G>T p.E893D (on ENST00000339266 / NM_001365621.1; = p.E890D on NM_014902.6) | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DMXL1 | c.3844C>G p.L1282V | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DNAH11 | c.4058T>C p.V1353A | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); called by muse, mutect2
- DNAH14 | c.3395del p.G1132Afs*17 (on ENST00000445597; = p.G1516Afs*17 on NM_001367479.1) | Frame Shift Del (DEL) | VAF 53/347 reads (15%) | called by mutect2, pindel, varscan2
- DNAH5 | c.7257del p.E2420Kfs*24 | Frame Shift Del (DEL) | VAF 88/369 reads (24%) | called by mutect2, pindel, varscan2
- DNAH7 | c.5942G>T p.G1981V | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.3189C>A p.D1063E | Missense Mutation (SNP) | VAF 184/575 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- DNAH9 | c.11784C>A p.N3928K | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.196); called by muse, varscan2
- DNAJB1 | c.71_81del p.Y24Cfs*23 | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | called by mutect2, pindel
- DOK5 | c.845A>T p.Y282F | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DPF1 | c.267del p.P90Rfs*43 | Frame Shift Del (DEL) | VAF 129/265 reads (49%) | called by mutect2, pindel, varscan2
- DPP6 | c.2199C>A p.F733L (on ENST00000377770 / NM_001364500.2; = p.F671L on NM_001936.5) | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- DPRX | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DROSHA | c.4103A>T p.E1368V | Missense Mutation (SNP) | VAF 57/425 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DST | c.8581C>A p.H2861N | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- DST | c.4650+1G>C p.X1550_splice (on ENST00000361203 / NM_001374722.1; = p.X1224_splice on NM_015548.5) | Splice Site (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2
- DSTYK | c.1949-1G>T p.X650_splice | Splice Site (SNP) | VAF 44/83 reads (53%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.4648G>T p.D1550Y | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- EFHB | c.1331G>A p.R444K | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- EGFR | c.611A>G p.E204G | Missense Mutation (SNP) | VAF 74/561 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGFR | c.1013A>T p.N338I | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2
- EIF3H | c.1029G>T p.M343I | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ELF1 | c.529+1G>T p.X177_splice | Splice Site (SNP) | VAF 62/105 reads (59%) | called by muse, mutect2, varscan2
- EME1 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENG | c.719T>A p.L240Q | Missense Mutation (SNP) | VAF 118/209 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ENPEP | c.2152-1G>T p.X718_splice | Splice Site (SNP) | VAF 27/132 reads (20%) | called by muse, mutect2, varscan2
- EPHA10 | c.2238A>T p.Q746H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERCC4 | c.1425del p.E476Nfs*17 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- ERCC4 | c.2008C>G p.R670G | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EXO1 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 113/355 reads (32%) | called by muse, mutect2, varscan2
- EXOSC4 | c.713A>G p.E238G | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, varscan2
- EYS | c.326C>A p.T109K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- F5 | c.161T>A p.L54* | Nonsense Mutation (SNP) | VAF 49/148 reads (33%) | called by muse, mutect2, varscan2
- FAM135B | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM181A | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- FBXL3 | c.902A>G p.D301G | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- FKBP6 | c.311G>T p.R104I | Missense Mutation (SNP) | VAF 164/518 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- FMNL3 | c.1074G>T p.K358N | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FMNL3 | c.788C>A p.P263Q | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSHR | c.2027C>A p.P676H | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by mutect2, varscan2
- FUT5 | c.272T>A p.L91Q | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- FYTTD1 | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- G6PC | c.961G>T p.V321F | Missense Mutation (SNP) | VAF 53/342 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GABPA | c.968G>C p.W323S | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT13 | c.981del p.W327Cfs*75 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | called by mutect2, pindel, varscan2
- GARRE1 | c.2792G>T p.G931V | Missense Mutation (SNP) | VAF 27/555 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GCN1 | c.2056C>G p.L686V | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.15); called by muse, mutect2
- GCSAM | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 96/461 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- GHR | c.922G>T p.G308* | Nonsense Mutation (SNP) | VAF 51/667 reads (8%) | called by muse, mutect2
- GHSR | c.679T>C p.C227R | Missense Mutation (SNP) | VAF 108/533 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GMNC | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 122/337 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- GNS | c.280A>G p.S94G | Missense Mutation (SNP) | VAF 39/497 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- GPR132 | c.757G>C p.V253L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- GRAMD4 | c.793A>T p.N265Y | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRB10 | c.1125G>T p.E375D (on ENST00000398812; = p.E329D on NM_001001549.3) | Missense Mutation (SNP) | VAF 143/542 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN2B | c.2896G>T p.V966L | Missense Mutation (SNP) | VAF 231/523 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GRK7 | c.1483del p.V495Wfs*21 | Frame Shift Del (DEL) | VAF 69/187 reads (37%) | called by mutect2, pindel, varscan2
- GRM6 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2
- H1-7 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2
- HECW1 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HIVEP1 | c.4793C>T p.S1598L | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- HK2 | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 102/257 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMMR | c.2030A>T p.N677I | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- HOXC11 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HTR1F | c.578C>A p.P193Q | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNL2 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 251/539 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFT122 | c.3479G>A p.G1160D (on ENST00000348417 / NM_052989.3; = p.G1101D on NM_018262.4) | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.172); called by muse, mutect2
- IGHG3 | c.192dup p.L65Pfs*35 | Frame Shift Ins (INS) | VAF 60/515 reads (12%) | called by mutect2, pindel, varscan2
- IGKV2D-26 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2
- IL18R1 | c.431A>C p.Y144S | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.084); called by muse, mutect2
- IL1RAPL1 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL33 | c.618_644del p.H206_D214del | In Frame Del (DEL) | VAF 36/170 reads (21%) | called by mutect2, pindel
- IQCK | c.566T>G p.F189C | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IQSEC2 | c.356G>C p.R119P | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ITGA2B | c.50T>A p.V17E | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ITGB8 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 27/425 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.078); called by muse, mutect2
- ITIH6 | c.3388C>A p.P1130T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2
- ITPR2 | c.5314dup p.S1772Ffs*12 | Frame Shift Ins (INS) | VAF 22/210 reads (10%) | called by mutect2, pindel, varscan2
- ITPRIP | c.826A>G p.M276V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- KALRN | c.2055G>C p.Q685H | Missense Mutation (SNP) | VAF 56/417 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNH1 | c.2506del p.S836Afs*39 (on ENST00000271751 / NM_172362.3; = p.S809Afs*39 on NM_002238.4) | Frame Shift Del (DEL) | VAF 31/110 reads (28%) | called by mutect2, pindel, varscan2
- KCNK17 | c.290G>C p.S97T | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- KCNS1 | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KEL | c.866T>G p.L289R | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- KHNYN | c.431G>T p.W144L | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KIR2DL1 | c.763A>T p.I255F | Missense Mutation (SNP) | VAF 64/397 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KIR3DL3 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KLRC3 | c.692T>C p.I231T | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- KMT2D | c.15146dup p.L5050Afs*22 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | called by mutect2, pindel
- KRT13 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KRT16 | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 135/472 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- KSR2 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- LAMA4 | c.967-1G>A p.X323_splice (on ENST00000230538 / NM_001105206.3; = p.X316_splice on NM_002290.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 52/124 reads (42%) | called by muse, mutect2, varscan2
- LAMB1 | c.3392C>A p.A1131D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- LANCL2 | c.257A>T p.Q86L | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- LCE1C | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 263/472 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- LIG1 | c.1375del p.V459Cfs*9 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | called by mutect2, pindel, varscan2
- LILRA4 | c.826T>A p.S276T | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- LMX1A | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LRCH3 | c.424A>T p.T142S | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- LRCH3 | c.1498A>G p.I500V | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LRRC10 | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRC10B | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- LUZP2 | c.926C>A p.P309H | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- LYPD5 | c.137T>G p.L46R (on ENST00000377950 / NM_001031749.3; = p.L3R on NM_182573.2) | Missense Mutation (SNP) | VAF 58/338 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); called by muse, varscan2
- LZTS1 | c.1720G>T p.G574W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MAGEB6B | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- MAP4 | c.3124A>G p.K1042E | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MAP7D1 | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAPK3 | c.39G>T p.E13D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPK8IP1 | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, varscan2
- MARK1 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MBD1 | c.1100A>G p.Q367R (on ENST00000269468 / NM_001323950.1; = p.Q344R on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, varscan2
- MCM3AP | c.3429G>T p.E1143D | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MDC1 | c.5926G>C p.E1976Q | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MEFV | c.1356G>C p.L452= | Splice Region (SNP) | VAF 100/396 reads (25%) | called by muse, mutect2, varscan2
- MEGF11 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- MFAP1 | c.55del p.A19Pfs*16 | Frame Shift Del (DEL) | VAF 35/254 reads (14%) | called by mutect2, pindel, varscan2
- MGAM | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MICAL3 | c.5923G>T p.E1975* | Nonsense Mutation (SNP) | VAF 84/214 reads (39%) | called by muse, mutect2, varscan2
- MME | c.1501A>T p.N501Y | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- MNAT1 | c.403A>T p.K135* | Nonsense Mutation (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- MNDA | c.446A>T p.N149I | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOSPD2 | c.1129_1130delinsT p.N378Ifs*12 | Frame Shift Del (DEL) | VAF 64/240 reads (27%) | called by pindel, varscan2*
- MRC1 | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 151/306 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MRGPRX4 | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- MRO | c.440G>T p.S147I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- MRPS12 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MSR1 | c.129A>T p.Q43H | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- MUC16 | c.30653C>A p.S10218* | Nonsense Mutation (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- MUC16 | c.7589C>A p.S2530* | Nonsense Mutation (SNP) | VAF 69/149 reads (46%) | called by muse, mutect2, varscan2
- MUC19 | c.1530C>G p.C510W | Missense Mutation (SNP) | VAF 165/328 reads (50%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC6 | c.308C>A p.A103D | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MYRFL | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NAV2 | c.6017A>T p.E2006V (on ENST00000396087 / NM_001244963.2; = p.E1947V on NM_145117.5) | Missense Mutation (SNP) | VAF 52/346 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NAV3 | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCAM1 | c.545C>A p.T182K | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- NCAM2 | c.415A>T p.S139C | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NCKIPSD | c.1262dup p.T422Dfs*2 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- NDST4 | c.235A>T p.T79S | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NEK10 | c.956G>A p.C319Y | Missense Mutation (SNP) | VAF 89/268 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKX2-4 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NLRP12 | c.2803G>T p.V935L | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP12 | c.1680C>A p.S560R | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NLRP4 | c.1571C>A p.S524Y | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NLRP8 | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOBOX | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- NPAP1 | c.1430C>A p.S477Y | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- NPAP1 | c.2729_2745delinsG p.S910Cfs*12 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | called by pindel, varscan2*
- NPTXR | c.605A>T p.D202V | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NRXN1 | c.2608C>A p.Q870K | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NSD1 | c.5531G>T p.R1844M | Missense Mutation (SNP) | VAF 70/469 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NUDT12 | c.27G>T p.K9N | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OBP2B | c.380A>T p.K127M | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OCA2 | c.2271C>A p.H757Q | Missense Mutation (SNP) | VAF 56/354 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ONECUT1 | c.926G>T p.S309I | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR10C1 | c.352G>T p.A118S (on ENST00000622521; = p.A116S on NM_013941.3) | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- OR1C1 | c.639T>A p.C213* | Nonsense Mutation (SNP) | VAF 39/136 reads (29%) | called by muse, mutect2, varscan2
- OR2A5 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- OR2AK2 | c.443C>A p.A148E | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- OR2L5 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR2L8 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR2T2 | c.159C>A p.D53E | Missense Mutation (SNP) | VAF 55/536 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- OR52B4 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR52D1 | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52E2 | c.490_493delinsTTT p.L164Ffs*12 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by pindel, varscan2*
- OR5AP2 | c.552C>G p.Y184* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- OR5R1 | c.808A>T p.T270S | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR6C3 | c.723C>A p.H241Q | Missense Mutation (SNP) | VAF 101/299 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR9G1 | c.440C>A p.S147* | Nonsense Mutation (SNP) | VAF 36/294 reads (12%) | called by muse, mutect2, varscan2
- OSBPL3 | c.1534A>T p.R512* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- OVCH1 | c.1820C>A p.P607Q | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- PACS2 | c.2144C>A p.A715E | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PAWR | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 122/323 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PCDHB14 | c.1969A>T p.T657S | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PCDHGA4 | c.1127C>A p.P376Q | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA6 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PCNX2 | c.2519A>T p.K840M | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- PCYOX1 | c.174dup p.K59Efs*9 | Frame Shift Ins (INS) | VAF 41/371 reads (11%) | called by mutect2, pindel, varscan2
- PDE10A | c.2177dup p.L727Afs*32 | Frame Shift Ins (INS) | VAF 78/228 reads (34%) | called by mutect2, pindel, varscan2
- PDE6A | c.1650T>A p.S550R | Missense Mutation (SNP) | VAF 65/378 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDLIM2 | c.980G>T p.W327L (on ENST00000397760; = p.W577L on NM_021630.6) | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PDZD2 | c.2568G>T p.K856N | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PDZRN4 | c.2107C>A p.H703N (on ENST00000402685 / NM_001164595.2; = p.H445N on NM_013377.4) | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PDZRN4 | c.2783A>T p.D928V (on ENST00000402685 / NM_001164595.2; = p.D670V on NM_013377.4) | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PEAR1 | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PEX3 | c.1042C>A p.L348M | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PGBD2 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PHF12 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHLDB1 | c.1486G>C p.A496P | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PLXDC1 | c.847A>T p.I283L | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLXNA4 | c.1300T>A p.S434T | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PLXNC1 | c.4024C>T p.H1342Y | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- POF1B | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.795); called by muse, varscan2
- POLR2M | c.780T>G p.D260E | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- POLR3B | c.5A>T p.D2V | Missense Mutation (SNP) | VAF 91/583 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POTEF | c.1632G>T p.K544N | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- POTEF | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 151/446 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPDPFL | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- PPIH | c.25G>C p.V9L | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PREX1 | c.2031C>A p.F677L | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRG4 | c.2597C>A p.P866H | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- PRICKLE1 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 86/933 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2
- PRKCI | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 59/246 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2
- PRKCI | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PRL | c.655T>C p.C219R | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRODH2 | c.678C>A p.S226R (on ENST00000301175; = p.S150R on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PRR32 | c.48_53del p.V17_V18del | In Frame Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- PRSS41 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 134/464 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRUNE2 | c.8374G>T p.D2792Y | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRUNE2 | c.8062C>A p.L2688I | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, varscan2
- PTGIR | c.917G>T p.W306L | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRB | c.4696T>A p.F1566I | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- PTPRD | c.1697C>A p.P566Q | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- PUM1 | c.1078_1081del p.F360Ifs*39 | Frame Shift Del (DEL) | VAF 30/190 reads (16%) | called by mutect2, pindel, varscan2
- R3HCC1L | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 30/161 reads (19%) | called by muse, mutect2, varscan2
- R3HDM1 | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- R3HDM1 | c.807G>T p.Q269H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- R3HDM2 | c.560A>T p.N187I | Missense Mutation (SNP) | VAF 133/326 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- RAB43 | c.601A>T p.S201C | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- RAD51AP2 | c.2076G>T p.M692I | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RANBP17 | c.2980G>T p.D994Y | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- RASAL1 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RB1 | c.1267G>T p.G423* | Nonsense Mutation (SNP) | VAF 55/190 reads (29%) | called by muse, mutect2, varscan2
- RBCK1 | c.1151A>G p.D384G (on ENST00000356286 / NM_031229.4; = p.D342G on NM_006462.6) | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- RBM12B | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM15B | c.2504G>T p.G835V | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM19 | c.2630G>C p.G877A | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- RBM27 | c.431G>C p.R144T | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- RCSD1 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 105/286 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- REEP6 | c.478G>T p.G160W | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RELN | c.1129G>T p.G377* | Nonsense Mutation (SNP) | VAF 110/463 reads (24%) | called by muse, mutect2, varscan2
- RERG | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.202); called by muse, varscan2
- RGS7 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- RHPN1 | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- RIMS1 | c.2960C>A p.S987* | Nonsense Mutation (SNP) | VAF 28/268 reads (10%) | called by muse, mutect2
- RIMS2 | c.2098G>T p.E700* (on ENST00000666250 / NM_001348490.2; = p.E508* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 32/189 reads (17%) | called by muse, mutect2, varscan2
- RNASE2 | c.484T>A p.*162Kext*46 | Nonstop Mutation (SNP) | VAF 10/44 reads (23%) | called by muse, varscan2
- RNASE3 | c.149G>C p.C50S | Missense Mutation (SNP) | VAF 97/364 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RRP1B | c.892-2A>G p.X298_splice | Splice Site (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2
- RTL1 | c.3145G>C p.E1049Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- RTL9 | c.2645G>T p.G882V | Missense Mutation (SNP) | VAF 85/148 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- RYR2 | c.12628G>T p.D4210Y | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- RYR3 | c.1355C>A p.P452H | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RYR3 | c.6869C>A p.A2290D (on ENST00000389232; = p.A2291D on NM_001036.6) | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SARDH | c.61dup p.R21Pfs*100 | Frame Shift Ins (INS) | VAF 10/107 reads (9%) | called by mutect2, pindel
- SCN11A | c.1964A>T p.D655V | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- SCN3A | c.3193A>G p.R1065G | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SCN3A | c.1653A>T p.K551N | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- SCN7A | c.445A>T p.N149Y | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SDHAF4 | c.165A>T p.E55D | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SEMA5A | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SEMA5A | c.509C>A p.T170K | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, varscan2
- SEPHS2 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SERPINC1 | c.983A>T p.E328V | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- SERPINE1 | c.732C>A p.Y244* | Nonsense Mutation (SNP) | VAF 80/256 reads (31%) | called by muse, varscan2
- SESTD1 | c.1732G>T p.D578Y | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SHROOM3 | c.3941G>A p.S1314N | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC13A5 | c.731G>C p.S244T | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC22A16 | c.1711dup p.R571Kfs*7 | Frame Shift Ins (INS) | VAF 63/173 reads (36%) | called by mutect2, pindel, varscan2
- SLC23A3 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); called by muse, varscan2
- SLC23A3 | c.459T>A p.H153Q | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, varscan2
- SLC26A7 | c.538A>T p.S180C | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC30A6 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SLC45A2 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 88/431 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLCO4A1 | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 72/417 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SMAD9 | c.322A>T p.K108* | Nonsense Mutation (SNP) | VAF 47/85 reads (55%) | called by muse, mutect2, varscan2
- SMARCA4 | c.4153G>T p.E1385* | Nonsense Mutation (SNP) | VAF 98/226 reads (43%) | called by muse, mutect2, varscan2
- SMARCAL1 | c.1941G>T p.K647N | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMG7 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- SNRPB | c.686-1G>T p.X229_splice | Splice Site (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- SOX11 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPATA31A7 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 123/358 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SPEF1 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPEG | c.8380G>T p.A2794S | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPOPL | c.386A>T p.K129M | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTA1 | c.4192C>A p.Q1398K | Missense Mutation (SNP) | VAF 150/645 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SPTB | c.845T>G p.V282G | Missense Mutation (SNP) | VAF 123/584 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SSTR1 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ST8SIA5 | c.818C>A p.A273D | Missense Mutation (SNP) | VAF 40/139 reads (29%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STAG1 | c.1502G>T p.C501F | Missense Mutation (SNP) | VAF 170/413 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- STX1B | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SYMPK | c.2806G>A p.A936T | Missense Mutation (SNP) | VAF 57/562 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TAC1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TACC2 | c.4768G>T p.A1590S | Missense Mutation (SNP) | VAF 74/141 reads (52%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TADA2A | c.622G>T p.V208L | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TBL2 | c.700C>A p.H234N | Missense Mutation (SNP) | VAF 93/306 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TCEANC2 | c.573G>T p.Q191H | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, varscan2
- TCHHL1 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 212/474 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- TCL1A | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TECRL | c.789del p.N264Ifs*6 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | called by pindel, varscan2
- TG | c.1493G>T p.S498I | Missense Mutation (SNP) | VAF 149/487 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- TLX2 | c.801dup p.W268Lfs*99 | Frame Shift Ins (INS) | VAF 88/234 reads (38%) | called by mutect2, pindel, varscan2
- TMEM11 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 81/388 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM128 | c.124G>T p.E42* (on ENST00000382753 / NM_001297552.2; = p.E18* on NM_032927.3) | Nonsense Mutation (SNP) | VAF 40/117 reads (34%) | called by muse, mutect2, varscan2
- TMEM131 | c.5131A>T p.S1711C | Missense Mutation (SNP) | VAF 104/373 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- TMEM132B | c.2912T>C p.M971T | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TMEM132C | c.795C>A p.H265Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- TMEM132C | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TMEM132D | c.1879G>T p.G627* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- TMEM179 | c.694G>T p.V232F | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- TMEM232 | c.1202C>A p.S401* | Nonsense Mutation (SNP) | VAF 49/186 reads (26%) | called by muse, mutect2, varscan2
- TMEM232 | c.820T>A p.C274S | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM87B | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMPRSS15 | c.1101A>T p.E367D | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- TMPRSS15 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TNIP3 | c.185C>T p.T62I (on ENST00000509841 / NM_001244764.2; = p.T55I on NM_001128843.2) | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TNXB | c.8849A>T p.Q2950L (on ENST00000647633; = p.Q2703L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- TOP2A | c.2377A>T p.R793W | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TPH2 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TPP2 | c.3157C>T p.L1053F | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TRIM10 | c.363C>A p.C121* | Nonsense Mutation (SNP) | VAF 20/114 reads (18%) | called by muse, varscan2
- TRIM22 | c.773G>T p.R258M | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- TRIM43 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- TRIM49B | c.433C>A p.Q145K | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM71 | c.206G>A p.C69Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2
- TRIM71 | c.207C>A p.C69* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | called by muse, varscan2
- TRPS1 | c.1220A>C p.D407A (on ENST00000220888 / NM_001330599.2; = p.D420A on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.70109G>T p.G23370V (on ENST00000591111; = p.G15946V on NM_003319.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.5723G>A p.G1908D (on ENST00000591111; = p.G1862D on NM_003319.4) | Missense Mutation (SNP) | VAF 16/117 reads (14%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TYW1 | c.1209G>T p.E403D | Missense Mutation (SNP) | VAF 66/694 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2
- TYW1B | c.1017G>T p.E339D | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by mutect2, varscan2
- UBR5 | c.4124G>T p.S1375I | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ULK2 | c.1104G>C p.M368I | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC79 | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 183/530 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- UNC80 | c.3617C>A p.A1206E | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UQCRC2 | c.390-2A>T p.X130_splice | Splice Site (SNP) | VAF 48/166 reads (29%) | called by muse, varscan2
- USP29 | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- USP50 | c.516G>T p.Q172H (on ENST00000616326; = p.Q163H on NM_203494.5) | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- VCAN | c.6163G>C p.D2055H | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- VGLL3 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- VPS13D | c.9287G>T p.W3096L | Missense Mutation (SNP) | VAF 84/418 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- VPS35L | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR33 | c.292A>T p.M98L | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); called by muse, mutect2
- WDR75 | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- XRN2 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- ZBED1 | c.2031G>T p.L677F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.121); called by muse, varscan2
- ZBED8 | c.1245G>T p.W415C | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZIC1 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 78/222 reads (35%) | called by muse, mutect2, varscan2
- ZMYND8 | c.1072G>T p.G358W (on ENST00000311275 / NM_001363741.2; = p.G378W on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF18 | c.306del p.K103Nfs*11 | Frame Shift Del (DEL) | VAF 34/273 reads (12%) | called by mutect2, pindel, varscan2
- ZNF180 | c.1133A>T p.E378V | Missense Mutation (SNP) | VAF 133/300 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ZNF208 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF251 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF26 | c.243del p.R81Sfs*36 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- ZNF469 | c.6496G>A p.V2166M (on ENST00000437464; = p.V2194M on NM_001367624.2) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, varscan2
- ZNF503 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ZNF526 | c.1047G>C p.Q349H | Missense Mutation (SNP) | VAF 109/284 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZNF534 | c.1157G>T p.R386L (on ENST00000332323 / NM_001143939.3; = p.R373L on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF536 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF536 | c.3342G>T p.Q1114H | Missense Mutation (SNP) | VAF 92/142 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ZNF541 | c.3963C>G p.I1321M | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF611 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- ZNF618 | c.338-2A>T p.X113_splice | Splice Site (SNP) | VAF 129/222 reads (58%) | called by muse, mutect2, varscan2
- ZNF716 | c.738T>A p.C246* | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- ZNF729 | c.2420G>T p.W807L | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF749 | c.726T>A p.Y242* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- ZNF76 | c.1051G>T p.G351C | Missense Mutation (SNP) | VAF 45/399 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZNF761 | c.268G>T p.V90F | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- ZNF852 | c.1199G>T p.R400L | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ZNRF2 | c.127del p.A43Pfs*100 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- ZP4 | c.668G>T p.C223F | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZRANB3 | c.2146C>A p.Q716K | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, varscan2
- ZSCAN4 | c.1250C>A p.T417N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- A1BG | c.756A>C p.V252= | Silent (SNP) | VAF 58/497 reads (12%) | called by muse, mutect2, varscan2
- ABCA6 | c.1464A>G p.K488= | Silent (SNP) | VAF 50/142 reads (35%) | called by muse, mutect2, varscan2
- ACSF3 | c.1710C>T p.I570= | Silent (SNP) | VAF 69/202 reads (34%) | called by muse, mutect2, varscan2
- ADAM19 | c.894C>A p.A298= | Silent (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.1107C>T p.H369= | Silent (SNP) | VAF 55/323 reads (17%) | catalogued as rs558484648; called by muse, mutect2, varscan2
- ADCY2 | c.1485C>G p.T495= | Silent (SNP) | VAF 26/204 reads (13%) | catalogued as COSV57886538; called by muse, mutect2, varscan2
- ADGRG4 | c.3909G>A p.E1303= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs748127374; called by muse, mutect2, varscan2
- ADH1B | c.654C>A p.A218= | Silent (SNP) | VAF 127/287 reads (44%) | called by muse, mutect2, varscan2
- ADNP | c.310A>C p.R104= | Silent (SNP) | VAF 61/228 reads (27%) | catalogued as rs372001392; called by muse, mutect2, varscan2
- ANAPC2 | c.1653G>A p.E551= | Silent (SNP) | VAF 134/304 reads (44%) | called by muse, mutect2, varscan2
- ANK1 | c.663G>A p.V221= | Silent (SNP) | VAF 52/225 reads (23%) | called by muse, mutect2, varscan2
- ANKRD62 | c.1986T>A p.A662= | Silent (SNP) | VAF 65/143 reads (45%) | called by muse, mutect2, varscan2
- APBA1 | c.615C>T p.P205= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs377162175; called by muse, mutect2, varscan2
- BIRC6 | c.6912C>T p.D2304= | Silent (SNP) | VAF 30/362 reads (8%) | called by muse, mutect2
- C14orf39 | c.1485A>G p.T495= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2
- C8orf34 | c.1017T>A p.S339= | Silent (SNP) | VAF 42/262 reads (16%) | called by muse, mutect2, varscan2
- C8orf82 | c.444G>T p.L148= | Silent (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- CALN1 | c.216A>T p.P72= (on ENST00000329008 / NM_001017440.3; = p.P114= on NM_031468.4) | Silent (SNP) | VAF 73/241 reads (30%) | called by muse, mutect2, varscan2
- CATSPERG | c.2910C>A p.R970= | Silent (SNP) | VAF 34/223 reads (15%) | catalogued as rs1185699267; called by muse, mutect2, varscan2
- CCDC168 | c.4800A>T p.V1600= | Silent (SNP) | VAF 76/170 reads (45%) | called by muse, mutect2, varscan2
- CCDC74A | c.612G>C p.A204= | Silent (SNP) | VAF 52/532 reads (10%) | called by muse, mutect2
- CCER1 | c.558G>C p.P186= | Silent (SNP) | VAF 57/148 reads (39%) | called by muse, mutect2, varscan2
- CCL13 | c.285C>A p.T95= | Silent (SNP) | VAF 79/429 reads (18%) | catalogued as COSV99861636; called by muse, mutect2, varscan2
- CD22 | c.678G>T p.G226= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as COSV50050148; called by muse, mutect2, varscan2
- CDH17 | c.99C>A p.P33= | Silent (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2
- CDH18 | c.570C>G p.T190= | Silent (SNP) | VAF 24/230 reads (10%) | catalogued as COSV56910271; called by muse, mutect2, varscan2
- CDO1 | c.588G>T p.S196= | Silent (SNP) | VAF 83/293 reads (28%) | called by muse, mutect2, varscan2
- CDX1 | c.486C>T p.T162= | Silent (SNP) | VAF 61/142 reads (43%) | catalogued as rs753003920, COSV51567566; called by muse, mutect2, varscan2
- CENPE | c.7350T>A p.A2450= | Silent (SNP) | VAF 45/205 reads (22%) | called by muse, mutect2, varscan2
- CFHR1 | c.940C>A p.R314= | Silent (SNP) | VAF 96/687 reads (14%) | catalogued as rs771183075, COSV57629309; called by muse, mutect2
- CGB1 | c.456C>A p.L152= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs1156748774; called by muse, mutect2, varscan2
- CHST2 | c.873C>T p.F291= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV58886856; called by mutect2, varscan2
- CHST9 | c.1131C>A p.A377= | Silent (SNP) | VAF 18/161 reads (11%) | called by muse, mutect2, varscan2
- CLDN5 | c.312C>T p.C104= (on ENST00000618236 / NM_001363066.2; = p.C189= on NM_003277.4) | Silent (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- CLIP2 | c.2311C>A p.R771= | Silent (SNP) | VAF 69/226 reads (31%) | catalogued as COSV56278216; called by muse, mutect2, varscan2
- CNTN5 | c.621G>T p.V207= | Silent (SNP) | VAF 56/166 reads (34%) | called by muse, mutect2, varscan2
- CNTN5 | c.861C>A p.L287= | Silent (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- COL1A2 | c.2799T>C p.D933= | Silent (SNP) | VAF 243/653 reads (37%) | catalogued as rs751960243; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL20A1 | c.1569G>T p.L523= | Silent (SNP) | VAF 44/164 reads (27%) | called by muse, mutect2, varscan2
- COL5A3 | c.1662C>G p.G554= | Silent (SNP) | VAF 39/231 reads (17%) | called by muse, mutect2, varscan2
- CRB1 | c.2610C>T p.N870= | Silent (SNP) | VAF 38/166 reads (23%) | catalogued as rs1032233875; called by muse, mutect2, varscan2
- CT47B1 | c.393T>C p.L131= | Silent (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2547C>A p.I849= | Silent (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- CTNND2 | c.978G>T p.L326= | Silent (SNP) | VAF 67/330 reads (20%) | called by muse, varscan2
- DCHS1 | c.603G>T p.G201= | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- DEFA5 | c.202C>A p.R68= | Silent (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
- DICER1 | c.207G>T p.G69= | Silent (SNP) | VAF 128/527 reads (24%) | called by muse, mutect2, varscan2
- DMP1 | c.216A>G p.S72= | Silent (SNP) | VAF 38/231 reads (16%) | catalogued as rs766838624, COSV56822348; called by muse, mutect2, varscan2
- DNAH8 | c.12501C>A p.I4167= | Silent (SNP) | VAF 47/175 reads (27%) | called by muse, mutect2, varscan2
- DPP10 | c.285G>C p.V95= | Silent (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- DROSHA | c.750G>T p.R250= | Silent (SNP) | VAF 23/133 reads (17%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.11781G>T p.L3927= | Silent (SNP) | VAF 161/491 reads (33%) | called by muse, varscan2
- EPOR | c.444C>A p.P148= | Silent (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- EZHIP | c.900C>A p.A300= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- F11 | c.294T>C p.Y98= | Silent (SNP) | VAF 44/438 reads (10%) | called by muse, mutect2
- F12 | c.558G>T p.G186= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1375418434; called by muse, mutect2, varscan2
- F5 | c.999C>A p.T333= | Silent (SNP) | VAF 83/530 reads (16%) | catalogued as COSV100888811; called by muse, mutect2, varscan2
- FBN2 | c.5790C>A p.T1930= | Silent (SNP) | VAF 53/321 reads (17%) | called by muse, mutect2, varscan2
- FBXL19 | c.2016G>C p.R672= | Silent (SNP) | VAF 42/125 reads (34%) | called by muse, mutect2, varscan2
- FBXL7 | c.1092C>A p.T364= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV61649639; called by muse, mutect2, varscan2
- FBXO24 | c.399C>G p.A133= (on ENST00000241071 / NM_033506.3; = p.A171= on NM_012172.5) | Silent (SNP) | VAF 83/481 reads (17%) | called by muse, mutect2, varscan2
- FCGR3B | c.636C>T p.C212= | Silent (SNP) | VAF 46/254 reads (18%) | catalogued as COSV54209892; called by muse, mutect2, varscan2
- FGD2 | c.876T>A p.T292= | Silent (SNP) | VAF 86/242 reads (36%) | called by muse, mutect2, varscan2
- FOXF1 | c.828G>T p.A276= | Silent (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- FSCB | c.1851G>A p.E617= | Silent (SNP) | VAF 40/184 reads (22%) | catalogued as rs1566598246; called by muse, varscan2
- FSD1 | c.1401G>A p.Q467= | Silent (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- GCN1 | c.6171G>T p.V2057= | Silent (SNP) | VAF 20/202 reads (10%) | called by mutect2, varscan2
- GRIA1 | c.342C>T p.P114= | Silent (SNP) | VAF 82/453 reads (18%) | catalogued as rs1014455215, COSV53619670; called by muse, mutect2, varscan2
- GRIK4 | c.1308G>A p.Q436= | Silent (SNP) | VAF 75/180 reads (42%) | called by muse, mutect2, varscan2
- GRM8 | c.387G>T p.S129= | Silent (SNP) | VAF 81/320 reads (25%) | catalogued as rs781101693, COSV58836897; called by muse, mutect2, varscan2
- GUCY1A2 | c.1362G>A p.L454= | Silent (SNP) | VAF 41/158 reads (26%) | catalogued as rs916956093, COSV56486572; called by muse, mutect2, varscan2
- H2AC1 | c.138A>T p.A46= | Silent (SNP) | VAF 26/237 reads (11%) | called by muse, mutect2, varscan2
- HELQ | c.1887T>C p.C629= | Silent (SNP) | VAF 98/298 reads (33%) | called by muse, mutect2, varscan2
259 further variants in this file (0 protein-altering or splice-affecting, 125 silent, 134 other) are not listed here.
